Somatic mutation profile of tumor specimen TCGA-GD-A76B-01A (aliquot TCGA-GD-A76B-01A-11D-A32B-08) from TCGA case TCGA-GD-A76B, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 86.4 years (31,571 days).
Specimen TCGA-GD-A76B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e319ba19-35ba-4c91-bb6b-a3afccda6096.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GD-A76B-10A (Blood Derived Normal), aliquot TCGA-GD-A76B-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4254d5f0-1a6e-4752-baab-4ee67ef1d09d

The open-access MAF lists 193 somatic variants for this specimen: 151 protein-altering or splice-affecting, 41 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 41, Nonsense Mutation 12, Splice Site 5, Frame Shift Ins 2, Splice Region 2, RNA 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.783G>A p.L261= | Splice Region (SNP) | VAF 6/78 reads (8%) | catalogued as COSV65310263; called by muse, mutect2
- ABHD1 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs991636040, COSV53204701, COSV53206401; called by muse, mutect2
- ADAMTS3 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 76/532 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54386590; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52809805, COSV99442657; called by muse, mutect2, varscan2
- ALPI | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV55013666; called by muse, mutect2, varscan2
- ANO6 | c.2010G>C p.M670I | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV57657778; called by muse, mutect2, varscan2
- ARHGAP24 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV67837339; called by muse, mutect2, varscan2
- ARID1A | c.2632C>T p.Q878* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV61373252; called by muse, mutect2, varscan2
- ARMH3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV64233481; called by muse, mutect2, varscan2
- ARSJ | c.1642G>T p.G548* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100192427; called by muse, mutect2, varscan2
- ATXN10 | c.729-1G>A p.X243_splice | Splice Site (SNP) | VAF 26/97 reads (27%) | catalogued as COSV53294084, COSV99426696; called by muse, mutect2, varscan2
- BCL2L13 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58225052; called by muse, mutect2, varscan2
- C11orf71 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as rs1032419912, COSV57784052; called by muse, mutect2, varscan2
- C3orf20 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53782980; called by muse, mutect2, varscan2
- CA8 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV58770800, COSV58770882; called by muse, mutect2, varscan2
- CACNG4 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs772670298, COSV50924283; called by muse, mutect2, varscan2
- CD300C | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); catalogued as rs748644474, COSV58169762; called by mutect2, varscan2
- CD99 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as rs771793015, COSV66989209; called by muse, mutect2, varscan2
- CHD8 | c.3982G>A p.E1328K (on ENST00000646647 / NM_001170629.2; = p.E1049K on NM_020920.4) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63218829; called by muse, mutect2, varscan2
- CHRM1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756528929, COSV61006252; called by muse, mutect2, varscan2
- CIZ1 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV52970444; called by muse, mutect2, varscan2
- CKB | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV62379390; called by mutect2, varscan2
- CLCN5 | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100259784; called by muse, mutect2
- CNBD1 | c.1239C>A p.F413L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV73072239; called by muse, mutect2, varscan2
- CWC27 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs568150813, COSV66884329; called by muse, mutect2, varscan2
- DBX2 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.82); catalogued as COSV60336529; called by muse, mutect2
- DENND2C | c.708dup p.Y237Ifs*3 | Frame Shift Ins (INS) | VAF 12/126 reads (10%) | catalogued as rs771378748; called by mutect2, pindel
- DPY19L1 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60581183; called by muse, mutect2, varscan2
- DPY19L3 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as COSV60475025; called by muse, mutect2, varscan2
- EFCAB7 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV60683277; called by muse, mutect2, varscan2
- EIF2AK3 | c.2231C>G p.S744* | Nonsense Mutation (SNP) | VAF 113/395 reads (29%) | catalogued as COSV100303380; called by muse, mutect2, varscan2
- EIF2AK3 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV57545468; called by muse, varscan2
- ETV7 | c.807+1G>T p.X269_splice | Splice Site (SNP) | VAF 50/178 reads (28%) | catalogued as rs779724253, COSV60316226; called by muse, mutect2, varscan2
- FBXL13 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57535475, COSV57542051; called by muse, mutect2, varscan2
- FCGR1A | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | catalogued as COSV100977258, COSV64985725; called by muse, mutect2, varscan2
- FCGR2A | c.909C>G p.I303M (on ENST00000271450 / NM_001136219.3; = p.I302M on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV99614941; called by muse, mutect2, varscan2
- FCN3 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54640661; called by muse, mutect2
- FMO3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV63006598; called by muse, mutect2, varscan2
- FREM2 | c.6404G>A p.R2135Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs149325030; called by muse, mutect2, varscan2
- GEMIN4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.947); catalogued as rs531320666, COSV56745081; called by muse, mutect2, varscan2
- GJB2 | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs1036073348, COSV67010551; called by muse, mutect2, varscan2
- GOLGB1 | c.5432G>A p.C1811Y | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61462502; called by muse, mutect2, varscan2
- GRM1 | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.11); catalogued as COSV51112912, COSV51381583; called by muse, mutect2
- GSAP | c.764C>G p.S255* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99989957; called by muse, varscan2
- HECTD2 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53219229, COSV53222895; called by muse, mutect2, varscan2
- HERC1 | c.9575G>A p.R3192K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as rs769687179, COSV71246353; called by muse, mutect2, varscan2
- HIVEP1 | c.3662G>A p.G1221E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV65099284; called by muse, mutect2, varscan2
- HMCN1 | c.12577G>A p.D4193N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54882228; called by muse, mutect2, varscan2
- HMGN5 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100815034, COSV63916492; called by muse, mutect2, varscan2
- HUWE1 | c.10328T>C p.I3443T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53337054; called by muse, mutect2, varscan2
- IRAK2 | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.436); catalogued as rs1239254460, COSV56529265; called by muse, mutect2, varscan2
- ITGA11 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1485083324, COSV59875405; called by muse, mutect2, varscan2
- JUP | c.1496A>G p.K499R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV60277208; called by muse, mutect2, varscan2
- KCNC4 | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100873563; called by muse, mutect2
- KDM6A | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV65037762, COSV65040087; called by muse, mutect2, varscan2
- KIF6 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV54669139; called by muse, mutect2, varscan2
- KRTAP10-8 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58166026; called by muse, mutect2, varscan2
- LAMA5 | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV53354357; called by muse, mutect2, varscan2
- LDLRAD4 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63334421; called by muse, mutect2
- LRRCC1 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV64482785; called by muse, mutect2, varscan2
- LRRN3 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57817904; called by muse, mutect2, varscan2
- MAP10 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV69362949; called by muse, mutect2, varscan2
- MAP2 | c.4426G>A p.V1476I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV52296205; called by muse, mutect2
- MBD2 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56500124; called by muse, mutect2, varscan2
- MCM4 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149597772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL16 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV54012400; called by muse, mutect2
- MIS18BP1 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs754884274, COSV60369418; called by muse, mutect2, varscan2
- MPP1 | c.947-1G>C p.X316_splice | Splice Site (SNP) | VAF 6/146 reads (4%) | catalogued as COSV65729220; called by muse, mutect2
- MRS2 | c.977T>G p.I326S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51233964; called by muse, mutect2, varscan2
- MUC17 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs71557226, COSV60281858; called by muse, mutect2, varscan2
- MYH2 | c.4786C>G p.H1596D | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV55432956; called by muse, mutect2, varscan2
- MYO9A | c.3813G>C p.K1271N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61848247; called by muse, mutect2, varscan2
- N4BP2L2 | c.1436A>G p.N479S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57227617; called by muse, mutect2, varscan2
- NEB | c.5473G>A p.E1825K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV50833911; called by muse, mutect2
- NEXMIF | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as COSV99279573; called by muse, mutect2, varscan2
- NKX2-2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV65820158; called by muse, mutect2
- NOP58 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51895802; called by muse, mutect2, varscan2
- NR0B1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs773110929, CM126132, COSV66763696; called by muse, mutect2, varscan2
- NR2F1 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV59067756; called by muse, mutect2, varscan2
- OR1A1 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.268); catalogued as COSV58403287; called by muse, mutect2, varscan2
- OR1L1 | c.935C>G p.P312R (on ENST00000373686; = p.P262R on NM_001005236.3) | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58935310; called by muse, mutect2
- PAQR8 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); catalogued as rs1188449236, COSV62442096; called by muse, mutect2, varscan2
- PCNA | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64770277, COSV64770349; called by muse, varscan2
- PCNT | c.7081C>G p.Q2361E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV64025764; called by muse, mutect2, varscan2
- PI4KB | c.1480G>C p.E494Q (on ENST00000368873 / NM_001369623.1; = p.E506Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV55015642; called by muse, mutect2, varscan2
- PIK3R4 | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs764393929, COSV63239437; called by muse, mutect2, varscan2
- PKD2 | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | catalogued as COSV99416811; called by muse, mutect2, varscan2
- PLCH1 | c.3371C>G p.S1124* (on ENST00000340059 / NM_001130960.2; = p.S1116* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100395521; called by muse, mutect2, varscan2
- PPM1B | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV56765339, COSV56767685; called by muse, mutect2, varscan2
- PPP1R15B | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV65815399; called by muse, mutect2, varscan2
- PPP1R16A | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1410112425, COSV52954160, COSV99477291; called by muse, mutect2, varscan2
- PPP2R3B | c.1353G>T p.G451= | Splice Region (SNP) | VAF 15/93 reads (16%) | catalogued as rs1319640073, COSV66812632, COSV66812752; called by muse, mutect2, varscan2
- PRDM4 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57304808; called by muse, mutect2, varscan2
- PRDX4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV65025858; called by muse, mutect2
- RERG | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV57000176; called by muse, mutect2, varscan2
- RIOK3 | c.887T>G p.L296R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772251; called by muse, mutect2
- RNF138 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV55233047, COSV99857332; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1412569809, COSV59086947; called by muse, mutect2, varscan2
- SDC4 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV65595114, COSV65595575; called by muse, mutect2, varscan2
- SEC24A | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs773455343, COSV59746116; called by muse, mutect2, varscan2
- SERINC3 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV54855630; called by muse, mutect2, varscan2
- SLC12A4 | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57925994; called by muse, mutect2, varscan2
- SLC13A1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520390; called by muse, mutect2
- SLC35C2 | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV54756192; called by muse, mutect2, varscan2
- SLC35C2 | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as rs939890691, COSV54756206; called by muse, mutect2
- SLC4A4 | c.2360C>T p.P787L (on ENST00000264485 / NM_001098484.3; = p.P743L on NM_003759.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761601854, COSV52616704; called by muse, mutect2, varscan2
- SLC5A4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV56668919; called by muse, mutect2, varscan2
- SNTG2 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57970832; called by muse, mutect2, varscan2
- SORT1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV56664721; called by muse, mutect2, varscan2
- SPDL1 | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54667291, COSV54667429; called by muse, mutect2, varscan2
- SPTBN1 | c.6466G>T p.E2156* | Nonsense Mutation (SNP) | VAF 47/173 reads (27%) | catalogued as COSV100441761; called by muse, mutect2, varscan2
- STK17A | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100081982, COSV60046165; called by muse, mutect2, varscan2
- STRN3 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62578680; called by muse, mutect2, varscan2
- SYCE2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1397624826, COSV53365808; called by muse, mutect2, varscan2
- SYN3 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60503400; called by muse, mutect2, varscan2
- TARS3 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60107580; called by muse, mutect2
- TCERG1L | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100893816; called by muse, mutect2
- TCF23 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV56078022; called by muse, mutect2
- TMEM104 | c.347-1G>A p.X116_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100120790, COSV59108214; called by muse, mutect2, varscan2
- TMEM170B | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65157180; called by muse, mutect2, varscan2
- TRHR | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV61233139; called by muse, mutect2, varscan2
- TRIP10 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99901128; called by muse, mutect2
- TRIP10 | c.1666G>A p.E556K (on ENST00000313244 / NM_001288962.2; = p.E500K on NM_004240.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs749931546, COSV55584956; called by muse, mutect2, varscan2
- TRPA1 | c.1292A>T p.N431I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV100083131, COSV51562790; called by muse, mutect2, varscan2
- TRPM7 | c.4177C>T p.H1393Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.139); catalogued as COSV57914092; called by muse, mutect2, varscan2
- TULP3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs567441567, COSV68117460; called by muse, mutect2, varscan2
- USH2A | c.8212G>A p.D2738N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs750687826, CM135010, COSV56335912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP19 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59731413; called by muse, mutect2, varscan2
- USP3 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51426474; called by muse, mutect2, varscan2
- USP38 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100189065; called by muse, mutect2, varscan2
- VAX2 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52265228; called by muse, mutect2, varscan2
- VMP1 | c.1091T>C p.L364S | Missense Mutation (SNP) | VAF 156/450 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV51865127; called by muse, mutect2, varscan2
- VWA8 | c.1928G>C p.R643T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55693246; called by muse, mutect2
- WIPF2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs768787767, COSV60272536; called by mutect2, varscan2
- XPO6 | c.1237G>C p.G413R | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV58964051; called by muse, mutect2
- ZAN | c.5845A>G p.I1949V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1284262431, COSV61805993; called by muse, mutect2, varscan2
- ZBTB7B | c.916G>A p.D306N (on ENST00000292176; = p.D340N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV52693181, COSV99420765; called by muse, mutect2
- ZC3H12A | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs765538707, COSV66103940; called by muse, mutect2, varscan2
- ZMPSTE24 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65638816; called by muse, mutect2
- ZNF217 | c.2980G>T p.G994W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56594641; called by muse, mutect2, varscan2
- ZNF284 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV101398921; called by muse, mutect2
- ZNF292 | c.6589C>G p.H2197D | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100371174, COSV60536366; called by muse, mutect2, varscan2
- ZNF382 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1404719740, COSV53086634; called by muse, mutect2, varscan2
- ZNF471 | c.1688G>T p.R563I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772228920, COSV57290185; called by muse, mutect2, varscan2
- ZNF621 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV59457551; called by muse, mutect2, varscan2
- ZSCAN1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs372224557, COSV56602391; called by muse, mutect2, varscan2
- AC245033.1 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ELF3 | c.164dup p.K56Efs*36 | Frame Shift Ins (INS) | VAF 54/148 reads (36%) | called by mutect2, pindel, varscan2
- FBXO42 | c.251-10_268del p.X84_splice | Splice Site (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel
- PRMT7 | c.1170_1174del p.Y391Pfs*54 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- ABCB1 | c.2652G>A p.L884= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs1382054370, COSV55946454; called by muse, varscan2
- ADGRG1 | c.1920C>G p.L640= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV65635266, COSV65636572; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3402T>C p.R1134= | Silent (SNP) | VAF 40/291 reads (14%) | catalogued as COSV51841714; called by muse, mutect2, varscan2
- ASAP1 | c.984G>A p.K328= | Silent (SNP) | VAF 57/203 reads (28%) | catalogued as COSV63045198; called by muse, mutect2, varscan2
- ATP2A2 | c.1620C>T p.V540= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1410765251, COSV100428381; called by muse, mutect2
- CACNA1B | c.489G>C p.R163= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV53115990, COSV53116516; called by muse, mutect2, varscan2
- CHMP2A | c.84G>A p.E28= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as COSV53396499; called by muse, mutect2, varscan2
- CHRNB2 | c.1023G>A p.E341= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100872532; called by muse, mutect2
- CLMP | c.576A>T p.R192= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV71649348; called by muse, mutect2
- DENND5A | c.660G>A p.R220= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100064494, COSV60231857; called by muse, mutect2
- DOCK7 | c.4665C>T p.L1555= (on ENST00000635253 / NM_001367561.1; = p.L1524= on NM_033407.3) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV52023762, COSV99222629; called by muse, mutect2, varscan2
- DYSF | c.5106C>T p.L1702= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs1558771751, COSV50274494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK3 | c.2052C>T p.L684= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs1013032001, COSV57544839; called by muse, varscan2
- FAM135A | c.264C>T p.I88= (on ENST00000370479 / NM_001351599.1; = p.I45= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV52048596; called by muse, mutect2, varscan2
- KIF14 | c.1923G>A p.S641= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as rs149518634, COSV66260207; called by muse, mutect2, varscan2
- LMTK2 | c.2910G>A p.S970= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs558810314, COSV51989581, COSV51991762; called by muse, mutect2, varscan2
- LRRC30 | c.843G>A p.P281= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as rs746083086, COSV67301394; called by muse, mutect2
- LUC7L | c.345C>T p.I115= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV53457107; called by muse, mutect2, varscan2
- MIEN1 | c.111G>A p.A37= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99506588; called by muse, mutect2, varscan2
- MYO15A | c.9468C>T p.L3156= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV52752963; called by muse, mutect2, varscan2
- NKRF | c.852G>C p.R284= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV58660892; called by muse, mutect2, varscan2
- NOM1 | c.658C>T p.L220= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as rs1230733507, COSV51979121; called by muse, mutect2, varscan2
- OR51M1 | c.201G>A p.L67= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV60783780, COSV60783954; called by muse, mutect2, varscan2
- OR5D16 | c.192C>T p.F64= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV65721411; called by muse, mutect2, varscan2
- PAFAH1B1 | c.333C>T p.V111= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs369129485; called by muse, mutect2, varscan2
- PIMREG | c.324C>G p.T108= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV51470354; called by muse, mutect2
- POTEE | c.819C>G p.L273= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs372916575, COSV100386894; called by muse, mutect2
- PRKACA | c.858G>A p.K286= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV54114798; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.858G>A p.E286= (on ENST00000421990 / NM_001136042.2; = p.E268= on NM_025267.3) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs987818233, COSV64181973; called by muse, mutect2, varscan2
- SH3BP5 | c.1221C>T p.S407= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV53743127; called by muse, varscan2
- SPTAN1 | c.1329C>T p.T443= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs193111526, COSV63985734; called by mutect2, varscan2
- STAT2 | c.1386C>T p.L462= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV58474520; called by muse, mutect2, varscan2
- SVEP1 | c.4479G>C p.V1493= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57030834, COSV57042084; called by muse, mutect2, varscan2
- TAF2 | c.3204G>A p.P1068= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as rs767191642, COSV65417025; called by muse, mutect2, varscan2
- TRGC1 | c.478C>T p.L160= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs370896093; called by mutect2, varscan2
- UGDH | c.1119G>A p.R373= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV57096901; called by muse, mutect2, varscan2
- UNC79 | c.1656G>A p.L552= (on ENST00000393151 / NM_001346218.2; = p.L375= on NM_020818.5) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV56376935; called by muse, mutect2, varscan2
- USP51 | c.33C>T p.S11= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV72351822; called by muse, mutect2
- WNT8A | c.924C>T p.V308= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV64230849; called by muse, mutect2, varscan2
- YY1AP1 | c.963G>A p.L321= (on ENST00000295566 / NM_139118.2; = p.L264= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs377332658, COSV55119905; called by muse, mutect2, varscan2
- ZNF224 | c.1641G>A p.K547= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV61241726, COSV61243427; called by muse, mutect2, varscan2
- OSTCP1 | n.348G>A | RNA (SNP) | VAF 25/117 reads (21%) | catalogued as rs752688930; called by muse, mutect2, varscan2
